MMRF case MMRF_2458 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6b8db43d-4236-4041-9eaf-78034ceb66f3

Demographics
Sex at birth: female; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.8 years (22,565 days); ISS stage: II; Days to last known disease status: 743 days (2.0 years); Days to last follow up: 743 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13: M Protein 5.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 81.2 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.22 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.48 mmol/L; Albumin 32 g/L; Total Protein 12.3 g/dL; Glucose 5.89 mmol/L.
- Day 56: M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 26.8 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.71 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 5.94 mmol/L.
- Day 155: M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.89 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 10.9 mmol/L.
- Day 225 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 9.63 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.72 mmol/L.
- Day 344 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 5.21 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.49 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 7.04 mmol/L.
- Day 435 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 5.3 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.91 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 533 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 4.45 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.16 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.23 mmol/L.
- Day 617: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.18 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 5.34 mmol/L.
- Day 743 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 5.12 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.18 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -13: Weight: 71 kg; Height: 164 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2458_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_2458_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
